Somatic mutation profile of tumor specimen CUPP-B38L-TTM1-A (aliquot CUPP-B38L-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B38L, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 59.9 years (21,864 days).
Specimen CUPP-B38L-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d97d33-35ab-437d-8142-f33efbe1d8e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B38L-NB1-A (Blood Derived Normal), aliquot CUPP-B38L-NB1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b554eab-793b-4752-8f2a-51c5437390b2

The open-access MAF lists 392 somatic variants for this specimen: 276 protein-altering or splice-affecting, 88 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 240, Silent 88, Intron 17, Nonsense Mutation 15, Frame Shift Del 11, RNA 4, 5'Flank 3, In Frame Del 3, 3'Flank 2, Frame Shift Ins 2, Translation Start Site 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RDH5 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs377029071, CM077621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.2498T>C p.I833T | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs267607119, CM090682; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.2372C>G p.A791G (on ENST00000326195 / NM_001025091.2; = p.A753G on NM_001090.3) | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748026265; called by muse, mutect2, varscan2
- ABHD1 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs1222519668; called by muse, mutect2, varscan2
- ABLIM3 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs142716823; called by muse, mutect2, varscan2
- AC004997.1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious, low confidence (0); catalogued as rs762652275, COSV99304634; called by muse, mutect2, varscan2
- ADGRV1 | c.16280T>A p.V5427E | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs760903910; called by muse, mutect2, varscan2
- AKNAD1 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.027); catalogued as rs373934680; called by muse, mutect2, varscan2
- AP5Z1 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs766057998, COSV62240645; called by muse, mutect2, varscan2
- ATP2B3 | c.900G>C p.E300D | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV54851584; called by muse, mutect2, varscan2
- AVPR2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV61686757; called by mutect2, varscan2
- BCAR1 | c.412_413del p.Q138Vfs*52 | Frame Shift Del (DEL) | VAF 53/185 reads (29%) | catalogued as rs773675824; called by mutect2, pindel, varscan2
- BCHE | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs149045543, COSV52259399; called by muse, mutect2, varscan2
- C11orf1 | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as rs142305825; called by muse, mutect2, varscan2
- C1QC | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.264); catalogued as rs560156356; called by muse, mutect2, varscan2
- C1orf131 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs564907684, COSV59642991; called by muse, mutect2, varscan2
- C1orf68 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs116458491; called by muse, mutect2, varscan2
- CCDC138 | c.321_323del p.E108del | In Frame Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs540279874; called by pindel, varscan2
- CCDC168 | c.20218A>C p.N6740H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs763888765; called by muse, mutect2, varscan2
- CCDC168 | c.17028A>T p.E5676D | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as rs1179738365; called by muse, mutect2, varscan2
- CD177 | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs750906870; called by muse, mutect2, varscan2
- CDH24 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.91); catalogued as rs147450903; called by muse, mutect2, varscan2
- CEACAM20 | c.1731C>G p.I577M | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV100386826; called by muse, mutect2, varscan2
- CEP162 | c.2060G>A p.R687K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs745660100; called by muse, mutect2, varscan2
- CFAP47 | c.4529G>T p.G1510V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs1569249709; called by muse, mutect2, varscan2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CNTN4 | c.256A>T p.I86F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375898825; called by muse, mutect2, varscan2
- CPNE4 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.989); catalogued as COSV70193306; called by muse, mutect2, varscan2
- CTAGE4 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 61/420 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs748389472; called by muse, mutect2, varscan2
- CTAGE8 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200679159; called by mutect2, varscan2
- CTNNBIP1 | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751743905; called by muse, mutect2, varscan2
- CWF19L2 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs781752146; called by muse, mutect2, varscan2
- DDR1 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.561); catalogued as rs746554342; called by muse, mutect2, varscan2
- DDX25 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs779956961, COSV54992616; called by mutect2, varscan2
- DENND2C | c.1255G>T p.E419* (on ENST00000393274 / NM_001256404.2; = p.E362* on NM_198459.4) | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as rs1036072817; called by muse, mutect2, varscan2
- EDA2R | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 45/82 reads (55%) | catalogued as rs141501145; called by muse, mutect2, varscan2
- EFCAB5 | c.2540A>T p.Y847F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as rs535743108; called by muse, mutect2, varscan2
- F9 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as COSV99496480; called by muse, mutect2, varscan2
- FAR1 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV61385508; called by muse, mutect2, varscan2
- FMO5 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150343605; called by muse, mutect2, varscan2
- GLI3 | c.4561G>T p.G1521W | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101229992; called by muse, varscan2
- GLMN | c.1482A>T p.L494F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs150536401; called by muse, mutect2, varscan2
- GOLGA6L6 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 36/540 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.417); catalogued as rs2452718, COSV71181158; called by muse, mutect2
- GOT1L1 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376370616; called by muse, mutect2, varscan2
- GRIA4 | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); catalogued as rs149552451; called by muse, mutect2, varscan2
- GRK6 | c.1705G>A p.E569K (on ENST00000355472 / NM_001004106.3; = p.A569= on NM_002082.3) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.019); catalogued as rs559029399; called by muse, mutect2, varscan2
- HCN4 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99983164; called by muse, mutect2
- HEPACAM2 | c.841T>C p.S281P (on ENST00000394468 / NM_001039372.4; = p.S269P on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as rs775978664; called by muse, mutect2, varscan2
- HNRNPDL | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs768442894; called by muse, mutect2, varscan2
- HTR1E | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs1562076153; called by muse, mutect2, varscan2
- HYDIN | c.7573C>T p.R2525C | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567604956, COSV59262303; called by muse, mutect2, varscan2
- ITK | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199801289; called by muse, mutect2, varscan2
- KAT14 | c.2194G>A p.V732I | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs764145827, COSV66607607; called by muse, mutect2, varscan2
- KBTBD11 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs755739343; called by muse, mutect2, varscan2
- KCNJ4 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57856618; called by muse, mutect2
- KIF5A | c.2953G>A p.G985S | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs371548640; called by muse, mutect2, varscan2
- KLHDC4 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.988); catalogued as rs769219137, COSV99566009; called by muse, mutect2, varscan2
- LCN2 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as rs1008518330; called by muse, mutect2, varscan2
- LENG8 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs757477130; called by muse, mutect2, varscan2
- LIN37 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99137462; called by mutect2, varscan2
- LMLN2 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs952522323; called by muse, mutect2, varscan2
- LRFN5 | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99035774; called by muse, mutect2, varscan2
- LRP1B | c.11269T>C p.Y3757H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs767501822, COSV67263382; called by muse, mutect2, varscan2
- MAGEB10 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV100775333, COSV100775336; called by muse, mutect2, varscan2
- MRAS | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs915324437; called by muse, mutect2
- MSR1 | c.893C>A p.P298Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.419); catalogued as rs1336332593; called by mutect2, varscan2
- MSTN | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs776358005; called by muse, mutect2, varscan2
- MUC12 | c.6293C>T p.T2098M (on ENST00000379442; = p.T1955M on NM_001164462.1) | Missense Mutation (SNP) | VAF 52/1014 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.788); catalogued as rs747660351; called by muse, mutect2
- MUC12 | c.8216C>T p.T2739I (on ENST00000379442; = p.T2596I on NM_001164462.1) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as rs760572685; called by mutect2, varscan2
- MUC5B | c.14771C>T p.S4924L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.283); catalogued as rs767870646, COSV71595867; called by muse, varscan2
- MYO1F | c.2749G>T p.D917Y | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1005137511; called by muse, mutect2, varscan2
- NBPF9 | c.2734A>G p.I912V | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782393903; called by muse, mutect2
- NDST1 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as rs1302728109; called by muse, mutect2, varscan2
- NLRP1 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446729781; called by muse, mutect2
- NOTCH1 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs1335400945; called by muse, mutect2, varscan2
- NUP210L | c.3974G>A p.R1325H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs565715933; called by muse, mutect2, varscan2
- NXPH4 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.799); catalogued as rs745393991; called by muse, mutect2, varscan2
- ODF3B | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1447115750; called by muse, mutect2, varscan2
- OR52D1 | c.14del p.N5Tfs*13 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | catalogued as rs1309925653; called by mutect2, pindel, varscan2
- OR52N1 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs753330009; called by muse, mutect2, varscan2
- OR52N2 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs777507232; called by muse, mutect2, varscan2
- OR6C75 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as COSV58551624, COSV58553074; called by mutect2, varscan2
- PBRM1 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56314548; called by muse, mutect2
- PCDH10 | c.2674C>A p.P892T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as rs1330146478; called by muse, mutect2
- PCNX1 | c.5029A>G p.S1677G | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1400926538; called by muse, mutect2, varscan2
- PER3 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs757633714; called by muse, mutect2, varscan2
- POTEI | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs1406444692; called by muse, mutect2
- PPP1R12B | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as rs759213373, COSV99295279; called by muse, mutect2
- PPP1R2B | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540914324; called by muse, mutect2, varscan2
- PRSS36 | c.2365A>T p.S789C | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as rs753687103; called by muse, mutect2, varscan2
- PRSS55 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV60807749; called by muse, mutect2, varscan2
- PSMB11 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as rs1231863829; called by muse, mutect2
- RASAL1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs375528107; called by muse, mutect2, varscan2
- RFXAP | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1209540070; called by muse, mutect2, varscan2
- RHNO1 | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.246); catalogued as rs750091697; called by muse, mutect2, varscan2
- RP1L1 | c.3765G>T p.Q1255H | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764441364; called by muse, varscan2
- RYR1 | c.7244G>A p.R2415Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.44); catalogued as rs201584482, COSV62095532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.2119C>T p.L707F | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs555127074; called by muse, mutect2
- SEMA4C | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs370503208; called by muse, mutect2, varscan2
- SERPING1 | c.1020G>C p.L340F | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV53543609; called by muse, mutect2, varscan2
- SLAMF1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99349300; called by mutect2, varscan2
- SLC24A1 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.501); catalogued as rs933577086; called by muse, mutect2, varscan2
- SLC29A1 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100505581; called by muse, mutect2, varscan2
- SLC38A8 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199667243; called by muse, mutect2, varscan2
- SLC41A1 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100900402; called by muse, mutect2, varscan2
- SLC5A8 | c.758G>T p.W253L | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs770091358; called by muse, mutect2, varscan2
- SLC9A7 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs745865153, COSV60379130; called by muse, mutect2, varscan2
- SORCS1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV99545392; called by muse, mutect2
- SPATA31A3 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs1253930601; called by mutect2, varscan2
- SPG11 | c.2228A>G p.E743G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs199617257; ClinVar: uncertain significance; called by muse, varscan2
- SSU72P5 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1398984858; called by muse, mutect2, varscan2
- STAP1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs759385053; called by muse, mutect2, varscan2
- TERF1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs748123134; called by muse, mutect2, varscan2
- TLE6 | c.1572_1575del p.F524Lfs*? (on ENST00000246112 / NM_001143986.2; = p.F401Lfs*? on NM_024760.3) | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs769902895; called by mutect2, varscan2
- TLR7 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs143823510, COSV66124504; called by muse, mutect2, varscan2
- TNC | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs150548325, COSV60792027; called by muse, mutect2, varscan2
- TNXB | c.2190C>G p.H730Q | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs759175756; called by muse, mutect2, varscan2
- TOE1 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1441675949; called by mutect2, varscan2
- TPX2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.058); catalogued as rs752131749; called by muse, mutect2, varscan2
- TRAM1L1 | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs755060097; called by muse, mutect2, varscan2
- TRPV3 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.857); catalogued as rs770315577; called by muse, mutect2, varscan2
- TTC28 | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as rs529615602, COSV67414258; called by muse, mutect2, varscan2
- UBR3 | c.4582G>C p.E1528Q | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV99774693; called by muse, mutect2, varscan2
- UGT1A4 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs149314940; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3215dup p.V1073Sfs*2 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | catalogued as rs750418659; called by mutect2, varscan2
- UNC93A | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs376096869, COSV57809581; called by muse, mutect2, varscan2
- UPK3BL2 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs774619252, COSV65024869; called by muse, mutect2
- UROD | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs766639207; called by muse, mutect2, varscan2
- USP33 | c.1936C>T p.L646F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62469276; called by muse, varscan2
- UTP20 | c.2653G>C p.A885P | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs201214965; called by muse, mutect2, varscan2
- VARS1 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747237558; called by muse, mutect2, varscan2
- VPS16 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs139527921; called by muse, mutect2, varscan2
- WDR81 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs781397816; called by muse, mutect2, varscan2
- WFIKKN1 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771270085; called by muse, mutect2, varscan2
- WIPF1 | c.17del p.P6Lfs*20 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as COSV99768385; called by mutect2, pindel, varscan2
- ZMIZ2 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs199769612; called by muse, mutect2, varscan2
- ZNF324B | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs1304267804; called by muse, mutect2
- ZNF773 | c.1133G>C p.R378P | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV56588366; called by muse, mutect2, varscan2
- ZNF837 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as rs759594701, COSV69892862; called by muse, mutect2, varscan2
- ZP3 | c.409C>G p.P137A (on ENST00000394857 / NM_001110354.2; = p.P86A on NM_007155.6) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs777422281; called by muse, mutect2, varscan2
- AADAT | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.078); called by muse, mutect2
- ABCC11 | c.3156C>G p.I1052M | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by mutect2, varscan2
- AC008687.4 | c.613del p.D205Tfs*19 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- AC011005.1 | c.1092C>A p.N364K | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2
- ACOD1 | c.773C>G p.A258G | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- ADGRL3 | c.2966T>A p.F989Y (on ENST00000506720 / NM_001322402.2; = p.F921Y on NM_015236.6) | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ADNP2 | c.3285G>T p.R1095S | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- ALS2 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMBRA1 | c.1888_1899del p.S630_E633del (on ENST00000458649 / NM_001367468.1; = p.S540_E543del on NM_017749.3 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 14/133 reads (11%) | called by mutect2, pindel, varscan2
- AMER1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANK1 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ANKRD60 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); called by mutect2, varscan2
- APBA2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2
- ARHGEF12 | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ATR | c.6870G>T p.W2290C | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by mutect2, varscan2
- BCHE | c.328T>A p.W110R | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BMP4 | c.956A>T p.D319V | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- BRCA1 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by mutect2, varscan2
- C8B | c.538A>T p.N180Y | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CAMTA1 | c.2994G>C p.Q998H | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- CCDC175 | c.1064T>G p.M355R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CD163 | c.1182_1184delinsTT p.L394Ffs*2 | Frame Shift Del (DEL) | VAF 21/152 reads (14%) | called by pindel, varscan2*
- CDH13 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH4 | c.443_450del p.P148Hfs*50 | Frame Shift Del (DEL) | VAF 42/159 reads (26%) | called by mutect2, pindel, varscan2
- CDHR2 | c.1766C>A p.S589Y | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CFAP47 | c.4528G>T p.G1510W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CFAP47 | c.8696C>A p.P2899Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by mutect2, varscan2
- CHRND | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CMPK1 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by mutect2, varscan2
- COL1A2 | c.1450G>T p.G484* | Nonsense Mutation (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2
- CYTH3 | c.398C>G p.A133G | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- DYRK4 | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ERO1B | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.221); called by muse, varscan2
- EXOSC1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- FAM111A | c.808A>G p.K270E | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FAM181B | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FAT3 | c.10627G>A p.E3543K | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- FBXW8 | c.1462G>T p.A488S (on ENST00000309909; = p.A526S on NM_012174.1) | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.077); called by muse, mutect2
- FGF4 | c.447C>T p.P149= | Splice Region (SNP) | VAF 14/85 reads (16%) | called by muse, varscan2
- FREM2 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- GFRA1 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- GJC1 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GPR15 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSTA1 | c.162dup p.V55Sfs*5 | Frame Shift Ins (INS) | VAF 29/181 reads (16%) | called by mutect2, varscan2
- HAUS7 | c.407A>C p.Q136P | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- HAVCR2 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- HCLS1 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by mutect2, varscan2
- IRF2BP2 | c.1607A>G p.Q536R | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ITGAM | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KHDRBS2 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- KIAA1210 | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- KIAA1549 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIRREL1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA5 | c.6389G>C p.R2130P | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, mutect2
- LHX8 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LPAR4 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MDFIC2 | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); called by mutect2, varscan2
- MDN1 | c.5681A>G p.D1894G | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- MGA | c.6847C>T p.P2283S (on ENST00000219905 / NM_001164273.1; = p.P2074S on NM_001080541.2) | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MPL | c.1907G>C p.*636Sext*13 | Nonstop Mutation (SNP) | VAF 23/202 reads (11%) | called by muse, mutect2, varscan2
- MRGPRG | c.713T>A p.L238Q | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MSANTD3 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- MTHFD2L | c.713G>T p.G238V (on ENST00000395759 / NM_001144978.2; = p.G180V on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- MUC17 | c.6352G>C p.E2118Q | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NAV3 | c.6150C>A p.H2050Q (on ENST00000397909 / NM_001024383.2; = p.H2028Q on NM_014903.6) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- NCAPD3 | c.3386A>T p.D1129V | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NECAP1 | c.14del p.L5Wfs*9 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | called by mutect2, pindel*, varscan2
- NEUROD6 | c.115A>T p.K39* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- NMUR2 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NRCAM | c.2813del p.P938Qfs*21 (on ENST00000379028 / NM_001371124.1; = p.P922Qfs*21 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- OAS3 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.049); called by muse, mutect2
- OR2T1 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5AN1 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8I2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR8I2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR8I2 | c.497_524delinsGGCGTTCTGTGATTCCGGCATCAATC p.L166Wfs*13 | Frame Shift Del (DEL) | VAF 40/159 reads (25%) | called by muse*, pindel, varscan2*
- ORC6 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- P2RX7 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | called by mutect2, varscan2
- P3H3 | c.1641G>T p.Q547H | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- PAN2 | c.232G>T p.V78F | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE3A | c.3252G>T p.K1084N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PDGFRB | c.3304G>C p.E1102Q | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2
- PIEZO2 | c.1961A>G p.E654G | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2
- PIK3R2 | c.867G>C p.Q289H | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); called by muse, mutect2
- PKP2 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLRG1 | c.1214T>C p.F405S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLXNA4 | c.2455C>A p.P819T | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, varscan2
- POU2F3 | c.1180C>G p.P394A | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PSG9 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PTPRQ | c.26A>C p.E9A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by mutect2, varscan2
- RAPGEF2 | c.2425G>T p.A809S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM46 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- REG3A | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.254); called by muse, mutect2
- RNF113A | c.198G>C p.M66I | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.44); called by muse, mutect2
- RPH3A | c.387G>C p.E129D (on ENST00000389385 / NM_001143854.2; = p.E125D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by mutect2, varscan2
- RPL8 | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by mutect2, varscan2
- RPL8 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RRP8 | c.1152A>T p.P384= | Splice Region (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- RTCA | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- RYR2 | c.14379C>A p.Y4793* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- SBNO1 | c.3067G>A p.D1023N (on ENST00000420886; = p.D1022N on NM_018183.5) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCLT1 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- SCNN1A | c.1939C>A p.L647M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- SIPA1 | c.894C>G p.H298Q | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SMIM23 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SMN1 | c.855A>C p.K285N | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SPOCK1 | c.292del p.V98* | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | called by mutect2, pindel*, varscan2
- SPRN | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- SSU72P3 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by mutect2, varscan2
- SUCNR1 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SULT1C3 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYCP2L | c.1303A>G p.R435G | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYNE1 | c.23671G>C p.D7891H (on ENST00000367255 / NM_182961.4; = p.D7820H on NM_033071.3) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D9B | c.1027A>T p.I343F | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- TESK1 | c.316C>G p.R106G | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TH | c.655G>T p.D219Y (on ENST00000381178 / NM_199292.3; = p.D188Y on NM_000360.4) | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- THEMIS2 | c.1435_1437del p.E479del | In Frame Del (DEL) | VAF 34/134 reads (25%) | called by pindel, varscan2
- TIAM1 | c.4420C>G p.P1474A | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- TNIK | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TOX2 | c.808C>G p.Q270E (on ENST00000358131 / NM_001098798.2; = p.Q219E on NM_032883.3) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TRAV21 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); called by muse, varscan2
- TTC6 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.423); called by muse, mutect2
- TTN | c.40421T>C p.V13474A (on ENST00000591111; = p.V6050A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | PolyPhen benign (0.435); called by muse, mutect2
- TTYH1 | c.1276T>A p.Y426N | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by mutect2, varscan2
- UBR1 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USH2A | c.13330C>A p.P4444T | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- VN1R2 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- WDPCP | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ZCWPW1 | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE9 | c.1433G>C p.C478S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF578 | c.566C>A p.S189* | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- ZNF605 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ZNF674 | c.507G>C p.K169N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZNF846 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZP4 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGAP6 | c.351A>G p.Q117= (on ENST00000374056 / NM_001365867.1; = p.Q140= on NM_001077665.2) | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs782398519; called by muse, mutect2, varscan2
- AL353579.1 | c.351G>A p.T117= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs751184214; called by muse, mutect2, varscan2
- AMER3 | c.324A>G p.T108= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as rs371156082; called by muse, mutect2, varscan2
- ARFGEF2 | c.1677G>C p.L559= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs771323104, COSV100904410, COSV64211674; called by mutect2, varscan2
- ARHGEF10 | c.1230G>A p.P410= (on ENST00000398564; = p.P385= on NM_014629.4) | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as rs1391410836, COSV50671736; called by muse, mutect2, varscan2
- ARMCX2 | c.1898G>A p.*633= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- ARMH4 | c.273G>A p.S91= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs1161059001, COSV50762857, COSV50774834; called by muse, mutect2, varscan2
- ATAD5 | c.1542T>C p.Y514= | Silent (SNP) | VAF 12/78 reads (15%) | called by mutect2, varscan2
- BCL3 | c.1185C>T p.L395= | Silent (SNP) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- BIN2 | c.888T>A p.T296= | Silent (SNP) | VAF 14/100 reads (14%) | called by mutect2, varscan2
- CALHM5 | c.105T>G p.S35= | Silent (SNP) | VAF 23/166 reads (14%) | catalogued as COSV62068296; called by muse, mutect2, varscan2
- CASZ1 | c.3225C>T p.A1075= | Silent (SNP) | VAF 59/180 reads (33%) | catalogued as rs144021797; called by muse, mutect2, varscan2
- CIT | c.4575G>C p.L1525= | Silent (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1083C>A p.S361= | Silent (SNP) | VAF 13/80 reads (16%) | called by mutect2, varscan2
- CPED1 | c.667T>C p.L223= | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- DAG1 | c.2214C>T p.D738= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as rs754599980; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHRS9 | c.165T>C p.H55= | Silent (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- DNAH7 | c.11565T>C p.L3855= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs368008760; called by muse, mutect2, varscan2
- DNAH8 | c.5061C>T p.F1687= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs765268910; called by muse, mutect2, varscan2
- DNAI1 | c.1752C>T p.A584= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as rs374753474, COSV54280857; called by muse, mutect2, varscan2
- DNER | c.1947C>T p.A649= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs770702460, COSV100520318; called by muse, mutect2, varscan2
- DOC2B | c.483G>A p.L161= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as rs1555523622; called by muse, mutect2, varscan2
- DPP7 | c.1095C>T p.T365= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as rs566571750, COSV65371231; called by muse, mutect2
- EDA2R | c.711C>T p.A237= | Silent (SNP) | VAF 61/108 reads (56%) | catalogued as rs1302302856, COSV99490893; called by muse, mutect2, varscan2
- EGR4 | c.900T>A p.A300= (on ENST00000545030; = p.A197= on NM_001965.4) | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as rs1157557132; called by muse, mutect2, varscan2
- EML1 | c.207T>C p.T69= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as rs377629941; called by muse, mutect2, varscan2
- ENC1 | c.327G>A p.R109= | Silent (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- EPPK1 | c.6621G>A p.T2207= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as rs781802244, COSV101599873; called by muse, mutect2
- EPS8L2 | c.153G>A p.Q51= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs753096193; called by muse, mutect2, varscan2
- FAM135B | c.1941C>A p.T647= | Silent (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- FAT3 | c.3033G>T p.R1011= | Silent (SNP) | VAF 44/217 reads (20%) | called by muse, mutect2, varscan2
- FER1L6 | c.2154C>T p.D718= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs188177034; called by muse, mutect2, varscan2
- FFAR3 | c.556C>T p.L186= | Silent (SNP) | VAF 42/252 reads (17%) | called by muse, mutect2, varscan2
- GANAB | c.2062C>T p.L688= | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- GPR101 | c.828A>G p.R276= | Silent (SNP) | VAF 69/172 reads (40%) | catalogued as rs781612893; called by muse, mutect2, varscan2
- GRM2 | c.1800C>T p.A600= | Silent (SNP) | VAF 14/136 reads (10%) | called by mutect2, varscan2
- GRM4 | c.2199G>T p.R733= | Silent (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- GRM4 | c.762G>A p.V254= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1281733643; called by mutect2, varscan2
- H2BC4 | c.69G>A p.Q23= | Silent (SNP) | VAF 23/248 reads (9%) | catalogued as COSV100020160; called by muse, mutect2
- KANK3 | c.924G>T p.V308= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- KL | c.1680G>T p.V560= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2, varscan2
- KRT6B | c.900C>A p.A300= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- LCE5A | c.78T>C p.P26= | Silent (SNP) | VAF 20/184 reads (11%) | called by mutect2, varscan2
- LOXHD1 | c.2100G>A p.T700= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as rs367826075; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- LTF | c.267C>T p.A89= | Silent (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
- LZTR1 | c.2190C>T p.G730= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as rs144092577; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEB10 | c.789G>C p.V263= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- MAN1C1 | c.1290C>T p.P430= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs771258387, COSV56043901; called by muse, mutect2, varscan2
- METTL21C | c.570C>A p.V190= | Silent (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- MSANTD3 | c.96G>T p.L32= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV100614581; called by muse, mutect2
- MTTP | c.855G>T p.T285= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2
- MYH2 | c.4260C>T p.L1420= | Silent (SNP) | VAF 17/209 reads (8%) | catalogued as rs201015317; called by muse, mutect2
- MYO18B | c.1500A>G p.R500= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as rs1312010077; called by muse, mutect2, varscan2
- NCBP1 | c.2166C>T p.T722= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs373220838, COSV100910620; called by muse, mutect2, varscan2
- NXPH2 | c.411T>C p.H137= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- PCDHA1 | c.129C>T p.T43= | Silent (SNP) | VAF 25/227 reads (11%) | catalogued as COSV100974572, COSV65373902; called by muse, mutect2
- PCDHA7 | c.486C>T p.I162= | Silent (SNP) | VAF 57/186 reads (31%) | catalogued as COSV65342726; called by muse, varscan2
- PER3 | c.3030A>G p.T1010= | Silent (SNP) | VAF 55/192 reads (29%) | catalogued as rs12023156; called by mutect2, varscan2
- PGK2 | c.543G>T p.L181= | Silent (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- PLAA | c.2073A>G p.K691= | Silent (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- PLIN4 | c.1593G>A p.V531= (on ENST00000301286; = p.V546= on NM_001367868.2) | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as rs1395275336; called by muse, mutect2, varscan2
- POLR3H | c.303A>G p.L101= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs1000935867; called by muse, mutect2, varscan2
- PSG6 | c.900G>A p.T300= | Silent (SNP) | VAF 57/310 reads (18%) | catalogued as rs778909429, COSV51832180; called by muse, varscan2
- RCC1 | c.51C>T p.I17= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV65779623; called by muse, mutect2, varscan2
- REXO1 | c.2892G>A p.R964= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as rs771793008; called by muse, mutect2, varscan2
- RSPH6A | c.69C>T p.A23= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as rs755044643; called by muse, mutect2, varscan2
- SAGE1 | c.1899G>A p.K633= | Silent (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- SAMD3 | c.1392A>T p.T464= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as rs111513742; called by muse, mutect2, varscan2
- SCLY | c.711C>T p.L237= (on ENST00000651534; = p.L229= on NM_016510.7) | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as rs150339508; called by muse, mutect2, varscan2
- SHE | c.534C>T p.S178= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as rs918875472; called by muse, mutect2, varscan2
- SIGMAR1 | c.339C>T p.S113= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as rs754738945; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC15A1 | c.402C>T p.L134= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs1402126584, COSV64711702; called by muse, mutect2
- SLIT3 | c.855G>A p.T285= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as rs367972639, COSV60619675; called by muse, mutect2, varscan2
- STK11 | c.1200G>A p.L400= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as rs368661707; ClinVar: likely benign; called by muse, varscan2
- TENM3 | c.1620G>C p.L540= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- TIGD7 | c.291G>A p.P97= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as rs199942857; called by muse, mutect2, varscan2
- TNPO2 | c.18C>T p.D6= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs775049018; called by muse, mutect2, varscan2
- TRBJ1-6 | c.18C>A p.P6= | Silent (SNP) | VAF 10/77 reads (13%) | called by mutect2, varscan2
- TREM2 | c.681G>A p.L227= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV58295920; called by muse, mutect2, varscan2
- TRPM2 | c.2535G>A p.R845= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs777601205, COSV55966963; called by muse, mutect2, varscan2
- UGT2B11 | c.63G>A p.G21= | Silent (SNP) | VAF 24/231 reads (10%) | catalogued as COSV101485213; called by muse, mutect2
- USH2A | c.2829C>A p.G943= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as rs397518007; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP26 | c.2361C>A p.S787= | Silent (SNP) | VAF 65/151 reads (43%) | catalogued as COSV63709718; called by muse, mutect2, varscan2
- VCAN | c.9051T>A p.A3017= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- WDFY4 | c.7281G>T p.T2427= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- ZAN | c.7143G>A p.P2381= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV61815101; called by mutect2, varscan2
- ZNF99 | c.2481G>A p.Q827= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- ZNF99 | c.27G>C p.V9= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- ABBA01000935.2 | n.446G>T | RNA (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2
- AC024940.1 | n.2165G>T | RNA (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- AC097527.1 | n.154G>A | RNA (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- AC233968.1 | n.130G>T | RNA (SNP) | VAF 6/78 reads (8%) | catalogued as rs1394609909; called by muse, mutect2
- AKAP9 | c.5698-2999C>T | Intron (SNP) | VAF 36/128 reads (28%) | catalogued as rs371318710; called by muse, mutect2, varscan2
- AL669831.3 | chr1:601436 C>T | 5'Flank (SNP) | VAF 10/45 reads (22%) | catalogued as rs373360530; called by mutect2, varscan2
- ATXN2 | c.3744+912C>T | Intron (SNP) | VAF 24/97 reads (25%) | catalogued as rs537349735; called by muse, mutect2, varscan2
- CCDC74B | c.296-255G>T | Intron (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- COMMD7 | c.526+110G>C | Intron (SNP) | VAF 31/130 reads (24%) | catalogued as rs776931869; called by muse, mutect2, varscan2
- ENTR1 | c.220+181G>C | Intron (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- ESRRB | c.1500+70G>T | Intron (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- FCGR3A | c.-36A>T | 5'UTR (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- GABRG3 | c.712+22C>A | Intron (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- GABRG3 | c.712+23A>C | Intron (SNP) | VAF 19/141 reads (13%) | catalogued as COSV100405614; called by muse, mutect2, varscan2
- KLK11 | c.294-52C>A | Intron (SNP) | VAF 12/72 reads (17%) | catalogued as COSV51575566; called by muse, varscan2
- MACF1 | c.15832-8473A>T | Intron (SNP) | VAF 56/254 reads (22%) | catalogued as rs1202007629; called by muse, mutect2, varscan2
- MLIP | c.613-11346T>A | Intron (SNP) | VAF 29/237 reads (12%) | called by muse, mutect2, varscan2
- NECAB2 | c.202-112G>T | Intron (SNP) | VAF 12/151 reads (8%) | called by muse, mutect2
- PIAS2 | c.25-12517C>T | Intron (SNP) | VAF 30/132 reads (23%) | catalogued as rs1213344955; called by muse, mutect2, varscan2
- RNA5SP283 | chr9:62801953 G>A | 3'Flank (SNP) | VAF 10/60 reads (17%) | catalogued as rs1260227903; called by muse, varscan2
- RNU6-1320P | chr2:94849256 C>A | 5'Flank (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2
- RNU6-1320P | chr2:94849257 C>A | 5'Flank (SNP) | VAF 15/142 reads (11%) | catalogued as rs540594361; called by muse, mutect2
- RPS29 | c.162+25T>C | Intron (SNP) | VAF 37/194 reads (19%) | called by muse, mutect2, varscan2
- SYNGR1 | c.483+1425C>T | Intron (SNP) | VAF 22/88 reads (25%) | catalogued as rs140460321; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4317-182C>G | Intron (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- TRAK1 | c.1744+66C>G | Intron (SNP) | VAF 54/156 reads (35%) | catalogued as rs780558831; called by muse, mutect2, varscan2
- XIRP2 | c.*1435G>A | 3'UTR (SNP) | VAF 23/183 reads (13%) | catalogued as rs1041519730; called by muse, mutect2
- ZNF721 | chr4:438623 A>T | 3'Flank (SNP) | VAF 31/124 reads (25%) | catalogued as rs782422576; called by muse, mutect2, varscan2
